Somatic mutation profile of tumor specimen TCGA-AA-3510-01A (aliquot TCGA-AA-3510-01A-01D-1408-10) from TCGA case TCGA-AA-3510, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 70.9 years (25,902 days).
Specimen TCGA-AA-3510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5362a2ba-0512-478c-8f56-cd234c701a64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3510-11A (Solid Tissue Normal), aliquot TCGA-AA-3510-11A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8091fa97-b1d1-41cf-8d04-9de39b9527a5

The open-access MAF lists 3,458 somatic variants for this specimen: 2,742 protein-altering or splice-affecting, 620 silent, 96 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,291, Silent 620, Nonsense Mutation 376, Intron 40, Splice Site 35, RNA 33, Splice Region 26, 3'UTR 14, Frame Shift Ins 7, 3'Flank 4, 5'UTR 3, Translation Start Site 3.

Variants (750 of 3,458; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 41/123 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 38/112 reads (34%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.7795G>T p.E2599* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs41293509, CD107522, CM118439, COSV66457437, COSV66461884; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKL5 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs267608501, CM102321, COSV66112168; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 53/161 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV62707942; called by muse, mutect2, varscan2
- CYP17A1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894154, CM063944, COSV64005017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.6562C>T p.R2188* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as rs200497972, COSV63281417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908596, CM080433, COSV61068347, COSV61068483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MECOM | c.2542C>T p.R848* (on ENST00000468789 / NM_001105078.4; = p.R1036* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1560118923, COSV52968817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- P2RY12 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121917885, CM035078, COSV56386348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs137853001, CM012633, COSV57282024; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 33/88 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.10939G>T p.E3647* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs1156566314, COSV66538422, COSV66541147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906853, CM116903, COSV59283256, COSV59285961; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TARBP2 | c.571G>T p.E191* (on ENST00000266987 / NM_134323.2; = p.E170* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 35/64 reads (55%) | hotspot (GDC flag); catalogued as COSV57199177; called by muse, mutect2, varscan2
- TBL1XR1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs1057517933, CM162314, COSV70501537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TCF4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as rs878853149, CM120282, COSV61890253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNI3K | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs202238194, COSV53950380; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TYRP1 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs121912778, CM052392, COSV66357901; ClinVar: pathogenic; called by muse, mutect2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3086G>T p.G1029V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59389315; called by muse, mutect2, varscan2
- A2ML1 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV55294290; called by muse, mutect2, varscan2
- A2ML1 | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs1370851573, COSV100228669; called by muse, mutect2
- A4GNT | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs775713265, COSV52628454; called by muse, mutect2, varscan2
- AATK | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1431860091, COSV100452734; called by muse, mutect2, varscan2
- ABCA1 | c.597A>C p.K199N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66059130; called by muse, mutect2, varscan2
- ABCA10 | c.2265A>C p.Q755H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99288345; called by muse, mutect2, varscan2
- ABCA10 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs764736598, COSV52225892; called by muse, mutect2, varscan2
- ABCA12 | c.2363T>A p.I788N (on ENST00000272895 / NM_173076.3; = p.I470N on NM_015657.3) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV55948117, COSV55966558; called by muse, mutect2, varscan2
- ABCA12 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs766593903, COSV55966574; called by muse, mutect2, varscan2
- ABCA12 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 43/118 reads (36%) | catalogued as COSV55966580; called by muse, mutect2, varscan2
- ABCA13 | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV70034370; called by muse, mutect2, varscan2
- ABCA13 | c.13876G>T p.E4626* | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | catalogued as rs1263321303, COSV101291284; called by muse, mutect2
- ABCA4 | c.6136G>T p.E2046* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV64670928; called by muse, mutect2, varscan2
- ABCA4 | c.3868G>A p.A1290T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143576497; called by muse, mutect2, varscan2
- ABCA5 | c.4231G>T p.E1411* | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | catalogued as COSV67017752; called by muse, mutect2, varscan2
- ABCA6 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as rs756114521, COSV52641162; called by muse, mutect2, varscan2
- ABCA9 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs772571287, COSV100382944; called by muse, mutect2, varscan2
- ABCA9 | c.2008C>A p.L670I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60632878; called by muse, mutect2, varscan2
- ABCA9 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV60620093; called by muse, mutect2, varscan2
- ABCB1 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201352027, COSV55949474; called by muse, mutect2, varscan2
- ABCB11 | c.581C>A p.S194* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | catalogued as COSV55595154, COSV55595243; called by muse, mutect2, varscan2
- ABCB11 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55595257; called by muse, mutect2, varscan2
- ABCB4 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 44/107 reads (41%) | catalogued as CM075940, COSV55938003; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCC1 | c.4133T>C p.V1378A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV60689341; called by muse, mutect2, varscan2
- ABCC8 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs577545383, COSV56849292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.3059C>T p.S1020L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV53977970; called by muse, mutect2, varscan2
- ABCE1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs550948053, COSV56846273; called by muse, mutect2, varscan2
- ABCG5 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV53211878; called by muse, mutect2, varscan2
- ABHD17C | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV51917334, COSV51918242; called by muse, mutect2, varscan2
- ABHD18 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1186504338, COSV66294266; called by muse, mutect2, varscan2
- ABI2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53691053; called by muse, mutect2
- ABL2 | c.271G>T p.E91* (on ENST00000502732 / NM_007314.4; = p.E76* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV61017315; called by muse, mutect2, varscan2
- AC013477.1 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV53654336; called by muse, mutect2, varscan2
- AC013489.1 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51552426; called by muse, mutect2, varscan2
- AC023055.1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as COSV60243721; called by muse, mutect2, varscan2
- AC126283.2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67097947; called by muse, mutect2, varscan2
- AC126283.2 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV67099278; called by muse, mutect2, varscan2
- AC127029.3 | c.794T>G p.F265C | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1470009286, COSV60111431; called by muse, mutect2
- ACACB | c.654G>A p.R218= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100622683; called by muse, mutect2, varscan2
- ACACB | c.6719G>A p.R2240Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs773800691, COSV58139408; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2, varscan2
- ACO1 | c.1001A>C p.K334T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV59381710; called by muse, mutect2, varscan2
- ACOT12 | c.1079A>C p.K360T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.091); catalogued as rs759543309, COSV100296861; called by muse, mutect2, varscan2
- ACOT12 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as rs766228561, COSV56892438; called by muse, mutect2, varscan2
- ACOT6 | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV66969081; called by muse, mutect2, varscan2
- ACSBG2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV53126114; called by muse, mutect2, varscan2
- ACSBG2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.756); catalogued as COSV53123446; called by muse, mutect2, varscan2
- ACSM1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs745476935, COSV54636001; called by muse, mutect2, varscan2
- ACSS3 | c.1356G>A p.E452= | Splice Region (SNP) | VAF 21/45 reads (47%) | catalogued as COSV54095575, COSV99699185; called by muse, mutect2, varscan2
- ACTG1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); catalogued as COSV59511204; called by muse, mutect2, varscan2
- ACTN1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.117); catalogued as rs201419872, COSV51994635; called by muse, mutect2, varscan2
- ACTR1B | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1276575768, COSV56705001; called by muse, mutect2, varscan2
- ACTR5 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.673); catalogued as COSV54761486; called by muse, mutect2, varscan2
- ACTR8 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV51637493; called by muse, mutect2, varscan2
- ACVR2A | c.1433G>T p.R478I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54022039; called by muse, mutect2, varscan2
- ACY3 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs754555869, COSV99662956; called by muse, mutect2
- ADA2 | c.1436C>A p.S479Y (on ENST00000262607; = p.S238Y on NM_177405.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52832285; called by muse, mutect2, varscan2
- ADAD1 | c.679T>A p.Y227N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs1268556793, COSV56645131; called by muse, mutect2, varscan2
- ADAM10 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53052914; called by muse, mutect2, varscan2
- ADAM2 | c.945G>T p.L315F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99697121; called by muse, mutect2
- ADAM8 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV69864933; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1254G>T p.M418I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56476207; called by muse, mutect2, varscan2
- ADAMTS1 | c.2543C>A p.S848Y | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV53171619, COSV99536034; called by muse, mutect2, varscan2
- ADAMTS12 | c.4625A>G p.D1542G | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61269229; called by muse, mutect2, varscan2
- ADAMTS16 | c.2073C>A p.F691L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56997206; called by muse, mutect2, varscan2
- ADAMTS18 | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51418855; called by muse, mutect2, varscan2
- ADAMTS18 | c.1949T>G p.F650C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV51418863; called by muse, mutect2, varscan2
- ADAMTS18 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1175274393, COSV99271988; called by muse, mutect2
- ADAMTS18 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs113981106, COSV51418872; called by muse, mutect2, varscan2
- ADAMTS20 | c.2844C>A p.Y948* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as COSV67134750; called by muse, mutect2, varscan2
- ADAR | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs767879893, COSV52712701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB2 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs767557012, COSV67214967; called by muse, mutect2, varscan2
- ADCY8 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); catalogued as COSV53901145; called by muse, mutect2, varscan2
- ADCYAP1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV99327492; called by muse, mutect2, varscan2
- ADD2 | c.1454T>G p.F485C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52465121; called by muse, mutect2, varscan2
- ADD2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs782189292, COSV52465148; called by muse, mutect2
- ADGRB2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.104); catalogued as rs1364413308, COSV99926007; called by muse, mutect2
- ADGRB3 | c.538A>C p.K180Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.966); catalogued as COSV65405912; called by muse, mutect2, varscan2
- ADGRB3 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV65405917, COSV65421680; called by muse, mutect2, varscan2
- ADGRB3 | c.1871G>A p.R624K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs765527940, COSV65391216, COSV65405921; called by muse, mutect2, varscan2
- ADGRB3 | c.2522C>T p.T841I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs757631514, COSV53252107; called by muse, varscan2
- ADGRB3 | c.3659C>A p.S1220Y | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53252123; called by muse, mutect2, varscan2
- ADGRE2 | c.2396T>G p.L799W | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV59694821; called by muse, mutect2, varscan2
- ADGRE3 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs1253041560, COSV53732501; called by muse, mutect2, varscan2
- ADGRF2 | c.479C>T p.S160L (on ENST00000296862 / NM_001368115.2; = p.S92L on NM_153839.7) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1383745668, COSV57289731; called by muse, mutect2, varscan2
- ADGRF3 | c.2545C>A p.H849N (on ENST00000311519 / NM_001145168.1; = p.H650N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61051466; called by muse, mutect2, varscan2
- ADGRF4 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.169); catalogued as COSV51954062; called by muse, mutect2, varscan2
- ADGRF5 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as COSV51936715; called by muse, mutect2, varscan2
- ADGRG4 | c.2189A>C p.K730T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV54961253; called by muse, mutect2, varscan2
- ADGRG4 | c.8948T>G p.F2983C | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54961265; called by muse, mutect2, varscan2
- ADGRL1 | c.4261G>A p.E1421K (on ENST00000340736 / NM_001008701.3; = p.E1416K on NM_014921.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs764585021, COSV61564445; called by muse, mutect2, varscan2
- ADGRL3 | c.2801T>G p.V934G (on ENST00000506720 / NM_001322402.2; = p.V866G on NM_015236.6) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.299); catalogued as COSV101546998; called by muse, mutect2, varscan2
- ADGRV1 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV101315737, COSV101316345; called by muse, mutect2
- ADM | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV53403438; called by muse, mutect2, varscan2
- ADNP2 | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51540523; called by muse, mutect2, varscan2
- ADSS1 | c.792C>T p.F264= | Splice Region (SNP) | VAF 12/35 reads (34%) | catalogued as rs530966674, COSV58274688; called by muse, mutect2, varscan2
- AFF3 | c.3029C>A p.S1010* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV57842940, COSV57859628; called by muse, mutect2, varscan2
- AFF4 | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99534802; called by muse, mutect2, varscan2
- AFG1L | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1475779033; called by muse, mutect2
- AFP | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as rs1483484643, COSV56925971; called by muse, mutect2, varscan2
- AGAP2 | c.1333G>T p.E445* (on ENST00000547588 / NM_001122772.2; = p.E109* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs1555199298, COSV57729863; called by muse, mutect2, varscan2
- AGGF1 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100461715; called by muse, mutect2, varscan2
- AGMO | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs769378096, COSV61105387, COSV61106804; called by muse, mutect2, varscan2
- AGTPBP1 | c.3062G>A p.R1021Q (on ENST00000357081 / NM_001330701.2; = p.R981Q on NM_015239.2) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.982); catalogued as rs1212529549, COSV61274268; called by muse, mutect2, varscan2
- AGTR1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200184769, COSV62557211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTR1 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62558999; called by muse, mutect2, varscan2
- AHCYL2 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV61485003; called by muse, mutect2, varscan2
- AHRR | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1467078013, COSV57089312; called by muse, mutect2, varscan2
- AHSG | c.214-1G>A p.X72_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV56608388; called by muse, mutect2, varscan2
- AICDA | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV57565179, COSV57565647; called by muse, varscan2
- AIDA | c.532T>G p.L178V | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60664759; called by muse, mutect2
- AIM2 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV63700672; called by muse, mutect2, varscan2
- AIMP1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 94/292 reads (32%) | catalogued as rs373122636; called by muse, mutect2, varscan2
- AK5 | c.1213C>A p.L405I (on ENST00000354567 / NM_174858.3; = p.L379I on NM_012093.4) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.711); catalogued as COSV100642547; called by muse, mutect2, varscan2
- AK9 | c.1045T>G p.Y349D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV53422281; called by muse, mutect2, varscan2
- AKAP13 | c.6187T>G p.S2063A (on ENST00000394518 / NM_007200.5; = p.S2067A on NM_006738.6) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV100773490; called by muse, mutect2, varscan2
- AKAP13 | c.7053G>T p.K2351N (on ENST00000394518 / NM_007200.5; = p.K2355N on NM_006738.6) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs780698233, COSV63463698; called by muse, mutect2, varscan2
- AKAP6 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55221226; called by muse, mutect2, varscan2
- AKAP6 | c.5488G>T p.D1830Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55221239; called by muse, mutect2, varscan2
- AKAP9 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV62351439; called by muse, mutect2, varscan2
- AKR1B10 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs373551927; called by muse, mutect2, varscan2
- AKT3 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99794941; called by muse, mutect2, varscan2
- AL121899.2 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs754241815, COSV67351386; called by mutect2, varscan2
- AL669918.1 | c.2453C>A p.S818Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV71270874, COSV71271138; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 42/117 reads (36%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A1 | c.1204T>G p.F402V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV52792612; called by muse, varscan2
- ALDH1A3 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.836); catalogued as rs188694308, COSV60902453; called by muse, mutect2, varscan2
- ALDH3A2 | c.1276T>G p.L426V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV51567703; called by muse, mutect2, varscan2
- ALK | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66577467; called by muse, mutect2, varscan2
- ALMS1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563989825, COSV52508595; called by muse, mutect2, varscan2
- ALOX12B | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); catalogued as rs769857850, COSV100046903; called by mutect2, varscan2
- ALOX5 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV65553154; called by muse, mutect2, varscan2
- AMBP | c.477A>C p.E159D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV54324355; called by muse, mutect2, varscan2
- AMD1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64387323; called by muse, mutect2, varscan2
- AMD1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs753517621, COSV64387769; called by muse, mutect2, varscan2
- AMER3 | c.1839C>A p.F613L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV58468132; called by muse, mutect2, varscan2
- AMPD1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs149424604, COSV100814939; called by muse, mutect2, varscan2
- ANAPC2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.462); catalogued as COSV100118853, COSV58808287; called by muse, mutect2, varscan2
- ANGPTL5 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV57533726; called by muse, mutect2, varscan2
- ANGPTL7 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as rs577777414, COSV63874479; called by muse, mutect2, varscan2
- ANK3 | c.12386C>A p.S4129Y (on ENST00000280772 / NM_001320874.2; = p.S650Y on NM_001149.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55067894; called by muse, mutect2, varscan2
- ANK3 | c.10454C>A p.S3485Y | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); catalogued as COSV55043627; called by muse, mutect2, varscan2
- ANK3 | c.5084C>T p.T1695I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV55067918; called by muse, mutect2, varscan2
- ANKEF1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs145101692; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51852428; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5095A>C p.K1699Q | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99782823; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.794); catalogued as COSV62006175; called by muse, varscan2
- ANKRD20A4P | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as rs1264293544, COSV100628490; called by muse, varscan2
- ANKRD28 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs746294289, COSV67519158; called by muse, mutect2, varscan2
- ANKRD35 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.758); catalogued as rs370459651, COSV62910939; called by muse, mutect2, varscan2
- ANKRD52 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV57285637; called by muse, mutect2, varscan2
- ANKRD6 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs1234779284, COSV60233455; called by muse, mutect2, varscan2
- ANKS4B | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61139621; called by muse, mutect2, varscan2
- ANKS4B | c.604A>C p.K202Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); catalogued as COSV61139630; called by muse, mutect2, varscan2
- ANO10 | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52733635; called by muse, mutect2, varscan2
- ANO3 | c.491T>G p.I164S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56798675; called by muse, varscan2
- ANO6 | c.1703A>G p.Y568C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57663862; called by muse, mutect2, varscan2
- ANOS1 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV52922782; called by muse, mutect2, varscan2
- ANTXR1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs370351341, COSV58009335; called by muse, mutect2, varscan2
- AOAH | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV51745393; called by muse, mutect2, varscan2
- AP3B2 | c.2844C>A p.F948L (on ENST00000261722; = p.F942L on NM_004644.5) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99916294; called by muse, mutect2, varscan2
- AP4B1 | c.953T>G p.F318C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433167700, COSV56725819; called by muse, mutect2, varscan2
- APBA2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as rs146641926; called by muse, mutect2, varscan2
- APBB2 | c.2158C>T p.R720* (on ENST00000295974 / NM_001166050.2; = p.R721* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | catalogued as rs1560589921, COSV55948589; called by muse, varscan2
- APC2 | c.5232A>C p.E1744D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV52020088; called by muse, mutect2, varscan2
- APCDD1L | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs906924591, COSV64487057; called by muse, mutect2, varscan2
- API5 | c.367A>C p.S123R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV66633990; called by muse, mutect2, varscan2
- API5 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV66633664; called by muse, mutect2, varscan2
- APOC2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs750370010, COSV52990404, COSV52990576; called by muse, mutect2, varscan2
- APOL3 | c.233G>A p.R78H (on ENST00000349314 / NM_145640.2; = p.R7H on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs753889786, COSV62580244; called by muse, mutect2, varscan2
- APOL6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs780403475, COSV68749391; called by muse, mutect2, varscan2
- APPL1 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99897575; called by muse, varscan2
- APPL1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs748607720, COSV55702014; called by muse, mutect2, varscan2
- ARAP2 | c.3885A>C p.E1295D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100394398; called by mutect2, varscan2
- ARFGEF1 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as COSV51602242; called by muse, mutect2, varscan2
- ARHGAP21 | c.5756A>C p.D1919A | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV57608512; called by muse, mutect2, varscan2
- ARHGAP21 | c.4778C>T p.A1593V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751762258, COSV57608515; called by muse, mutect2, varscan2
- ARHGAP22 | c.1895G>A p.R632K | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV50956804; called by muse, varscan2
- ARHGAP24 | c.1552G>T p.E518* (on ENST00000395184 / NM_001025616.3; = p.E425* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV51991051; called by muse, mutect2, varscan2
- ARHGAP5 | c.2585C>T p.S862L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61535076; called by muse, mutect2, varscan2
- ARHGDIA | c.337A>C p.K113Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53906893; called by muse, mutect2, varscan2
- ARHGEF10 | c.1880A>G p.E627G (on ENST00000398564; = p.E602G on NM_014629.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100034310; called by muse, mutect2, varscan2
- ARHGEF38 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.617); catalogued as rs762338044, COSV99486219; called by muse, varscan2
- ARHGEF4 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as rs1472538026, COSV100387904; called by muse, mutect2
- ARHGEF7 | c.1226G>A p.R409H (on ENST00000375741 / NM_001113511.2; = p.R231H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778093839, COSV54546717; called by muse, mutect2, varscan2
- ARL15 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 44/141 reads (31%) | catalogued as COSV72292464, COSV72292873; called by muse, mutect2, varscan2
- ARMC10 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 78/297 reads (26%) | catalogued as rs974342956, COSV58523086; called by muse, mutect2, varscan2
- ARMC2 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100933518; called by mutect2, varscan2
- ARMC2 | c.2348A>C p.K783T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64552051; called by muse, mutect2, varscan2
- ARMC4 | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs774313354, COSV53466650; called by muse, mutect2, varscan2
- ARNTL2 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.263); catalogued as COSV53827179; called by muse, mutect2
- ARPP21 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs140987024; called by muse, mutect2, varscan2
- ARSD | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101144362; called by muse, mutect2, varscan2
- ARSG | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1369350242, COSV71592584; called by muse, mutect2, varscan2
- ARSJ | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as rs747250767, COSV59536786; called by muse, varscan2
- ARSK | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187535; called by muse, mutect2, varscan2
- ARX | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66875532; called by muse, mutect2, varscan2
- ASB14 | c.1585A>G p.T529A | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55702027; called by muse, mutect2, varscan2
- ASB17 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV52411198; called by muse, mutect2, varscan2
- ASB5 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV99641522; called by muse, mutect2, varscan2
- ASB8 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs747598837, COSV58350916; called by mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2
- ASH1L | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64206888; called by muse, mutect2, varscan2
- ASH1L | c.1182T>G p.S394R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV100853321; called by muse, mutect2, varscan2
- ASH1L | c.123A>C p.K41N | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV64210379; called by muse, mutect2
- ASIC5 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV73332585; called by muse, mutect2, varscan2
- ASIC5 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs752632438, COSV73332561, COSV73332754; called by muse, mutect2, varscan2
- ASIC5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs145147748; called by muse, varscan2
- ASIP | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs758913102, COSV66588508; called by muse, mutect2, varscan2
- ASNSD1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144391161; called by muse, mutect2, varscan2
- ASPH | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101063965, COSV65245687; called by muse, mutect2, varscan2
- ASPH | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV62860360; called by muse, mutect2, varscan2
- ASPM | c.8045G>A p.R2682Q | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs777169562, COSV54133359; called by muse, mutect2, varscan2
- ASPRV1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100208463; called by muse, mutect2, varscan2
- ASTN1 | c.2762G>A p.G921D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV62500435; called by mutect2, varscan2
- ASXL1 | c.3682G>T p.E1228* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV60106341, COSV60111078, COSV60113023; called by muse, mutect2, varscan2
- ASXL3 | c.3770C>A p.S1257Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV52471894; called by muse, mutect2, varscan2
- ATE1 | c.756A>C p.K252N | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56438850; called by muse, mutect2, varscan2
- ATF7IP | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53768255, COSV99661141; called by muse, mutect2, varscan2
- ATG9B | c.527T>A p.L176H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV52507065; called by muse, mutect2, varscan2
- ATL1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV63296390; called by muse, mutect2, varscan2
- ATM | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs587779830, COSV53741732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs375152534, COSV99756488; called by muse, varscan2
- ATP13A5 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60867945; called by muse, mutect2, varscan2
- ATP2A2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV58048028; called by muse, mutect2, varscan2
- ATP2A2 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs773978831, COSV57875770, COSV57876130; called by muse, mutect2, varscan2
- ATP2C1 | c.1939A>C p.N647H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60758875; called by muse, mutect2, varscan2
- ATP7B | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as CM110337, COSV54440664; called by muse, mutect2, varscan2
- ATP8A2 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as rs368163155; called by muse, mutect2, varscan2
- ATP8B3 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs777333038, COSV59539910; called by muse, mutect2, varscan2
- ATP8B4 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV52717337, COSV52719277; called by muse, mutect2, varscan2
- ATRX | c.5090G>A p.S1697N | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as COSV64879653; called by muse, mutect2, varscan2
- ATRX | c.3810A>C p.R1270S | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV64879655; called by muse, mutect2, varscan2
- AVEN | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV60735050, COSV60735792; called by muse, mutect2, varscan2
- AXDND1 | c.863+2T>C p.X288_splice | Splice Site (SNP) | VAF 44/139 reads (32%) | catalogued as COSV100858309; called by muse, mutect2, varscan2
- AXDND1 | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62640603, COSV62642324; called by muse, mutect2, varscan2
- AXL | c.1558G>A p.E520K (on ENST00000301178 / NM_021913.5; = p.E511K on NM_001699.6) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV99996312; called by muse, mutect2, varscan2
- AZGP1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV52798355; called by muse, varscan2
- AZI2 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55422688; called by muse, mutect2, varscan2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV62563605; called by muse, varscan2
- B2M | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 32/110 reads (29%) | catalogued as COSV62564724, COSV62566483; called by muse, varscan2
- B3GALNT1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.058); catalogued as rs1362528658, COSV100251957, COSV57579825; called by muse, mutect2, varscan2
- B3GLCT | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs770760169, COSV58456618; called by muse, mutect2, varscan2
- B4GALNT3 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201901859, COSV56755014; called by muse, mutect2, varscan2
- B4GALNT4 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV57324425; called by muse, mutect2, varscan2
- BAG3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs876657746, COSV64842047; ClinVar: uncertain significance; called by muse, mutect2
- BAIAP3 | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs116346037; called by muse, mutect2, varscan2
- BANK1 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as rs546991706, COSV59846110; called by muse, mutect2
- BAZ2B | c.1902A>C p.E634D | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.956); catalogued as COSV58604929; called by muse, mutect2, varscan2
- BCAS3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.262); catalogued as COSV66777232; called by muse, mutect2, varscan2
- BCAS3 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs1321744067, COSV66777239; called by muse, mutect2, varscan2
- BCL10 | c.322A>C p.N108H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV65353990; called by muse, mutect2, varscan2
- BCLAF1 | c.2468A>C p.N823T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV50358829; called by muse, mutect2, varscan2
- BCLAF1 | c.2053A>C p.K685Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV50358830; called by muse, mutect2, varscan2
- BCLAF1 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 41/174 reads (24%) | catalogued as COSV62143856; called by muse, mutect2, varscan2
- BCO2 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs146534695, COSV63064631; called by muse, mutect2, varscan2
- BDP1 | c.1391G>T p.R464I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100703459, COSV62432641; called by muse, mutect2, varscan2
- BICDL1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV66908338; called by muse, mutect2, varscan2
- BICRAL | c.2516T>G p.F839C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.163); catalogued as COSV58407005; called by muse, mutect2, varscan2
- BICRAL | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100017992; called by muse, mutect2, varscan2
- BIRC6 | c.14548G>T p.E4850* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV70202505; called by muse, mutect2, varscan2
- BLOC1S5 | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55242196; called by muse, mutect2, varscan2
- BMP1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs886062818, COSV100109349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP15 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs782079720, COSV53139772; called by muse, mutect2, varscan2
- BMPR1A | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs767763451, COSV64407060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BOD1L1 | c.8462T>C p.L2821S | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV50025751; called by muse, mutect2, varscan2
- BORA | c.1076T>C p.I359T (on ENST00000613797; = p.I284T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100909669; called by muse, mutect2, varscan2
- BRCA1 | c.3774G>T p.E1258D | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs431825399, COSV58793940, COSV58802784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV54589734; called by muse, mutect2, varscan2
- BRDT | c.2725G>T p.D909Y | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100746275; called by muse, mutect2
- BRINP2 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs747290778, COSV100837981; called by muse, mutect2, varscan2
- BROX | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61799005; called by muse, mutect2, varscan2
- BRSK2 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV57545330; called by muse, mutect2, varscan2
- BRWD1 | c.4297C>T p.R1433* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as rs752494269, COSV60892572; called by muse, mutect2, varscan2
- BTAF1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs946512719, COSV56436316; called by muse, mutect2, varscan2
- BTBD10 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as rs1245744628, COSV53398654; called by muse, mutect2, varscan2
- BTBD11 | c.1419C>A p.F473L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV55034522, COSV99775308; called by muse, mutect2, varscan2
- BTBD11 | c.3238C>A p.L1080I (on ENST00000280758 / NM_001018072.2; = p.L617I on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV55029407; called by muse, mutect2, varscan2
- BTBD9 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.239); catalogued as rs1419185468, COSV58430808; called by muse, mutect2, varscan2
- C10orf90 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52958706; called by muse, mutect2, varscan2
- C10orf90 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as COSV52950938; called by muse, mutect2, varscan2
- C11orf65 | c.703A>C p.N235H | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV67597975; called by muse, mutect2
- C12orf42 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1255676381, COSV59386025; called by muse, varscan2
- C12orf42 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59386249; called by muse, varscan2
- C14orf39 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1421877446, COSV58780382; called by muse, mutect2, varscan2
- C14orf39 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 48/142 reads (34%) | catalogued as COSV58783372; called by muse, mutect2, varscan2
- C16orf72 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV59916491; called by muse, mutect2, varscan2
- C16orf89 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301302453, COSV60122446; called by muse, mutect2, varscan2
- C18orf54 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55618672; called by muse, mutect2, varscan2
- C1orf56 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV99764598; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, varscan2
- C2orf78 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.781); catalogued as rs758357092, COSV68518372; called by muse, mutect2, varscan2
- C3 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746085199, COSV55578737, COSV99836450; called by mutect2, varscan2
- C3AR1 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs768607158, COSV50818743, COSV99368193; called by muse, mutect2, varscan2
- C3AR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs56297048, COSV50820555; called by muse, mutect2, varscan2
- C4orf17 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as rs775366940, COSV56745020, COSV56746302; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C7 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV57470260; called by muse, mutect2, varscan2
- C7 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 13/132 reads (10%) | catalogued as COSV57471527, COSV57472522; called by muse, mutect2, varscan2
- C8orf34 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV61386582; called by muse, mutect2, varscan2
- C8orf58 | c.1088C>A p.S363Y (on ENST00000289989 / NM_001013842.3; = p.S355Y on NM_173686.3) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV51516047; called by muse, mutect2, varscan2
- C8orf74 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100261866; called by muse, mutect2, varscan2
- C8orf74 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV58754861; called by muse, mutect2, varscan2
- C9orf152 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1205656530, COSV68762701; called by muse, mutect2
- C9orf64 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV59032179, COSV59032806; called by muse, mutect2, varscan2
- CABLES1 | c.1238G>T p.R413I (on ENST00000256925 / NM_001100619.2; = p.R148I on NM_138375.2) | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56931300; called by muse, mutect2
- CABS1 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV56734050; called by muse, mutect2, varscan2
- CACNA1G | c.6887G>A p.G2296E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.169); catalogued as COSV61731830, COSV61738119; called by muse, mutect2, varscan2
- CACNA1H | c.2496C>A p.F832L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61983189, COSV61996773; called by mutect2, varscan2
- CACNA1H | c.5279T>G p.F1760C | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52356206; called by muse, mutect2, varscan2
- CACNA2D1 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62384742, COSV62384923; called by muse, mutect2, varscan2
- CACNA2D2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs568540115, COSV56565933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.1135A>C p.I379L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV55557569; called by muse, mutect2, varscan2
- CACNA2D3 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV55557579; called by muse, mutect2, varscan2
- CACUL1 | c.989A>C p.K330T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60995663; called by muse, mutect2, varscan2
- CADM1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs201626870, COSV59008985; called by muse, mutect2, varscan2
- CADM1 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV100522469; called by muse, varscan2
- CAGE1 | c.1329A>C p.K443N (on ENST00000512086; = p.K307N on NM_205864.3) | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV57078996; called by muse, mutect2, varscan2
- CALD1 | c.1777C>T p.R593* (on ENST00000361675 / NM_033138.4; = p.R338* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV62647174; called by muse, mutect2, varscan2
- CALHM1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs764167413, COSV61707582; called by muse, mutect2, varscan2
- CALN1 | c.378T>C p.F126= (on ENST00000329008 / NM_001017440.3; = p.F168= on NM_031468.4) | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as COSV61140756; called by muse, mutect2, varscan2
- CALR3 | c.1099A>T p.K367* | Nonsense Mutation (SNP) | VAF 51/166 reads (31%) | catalogued as COSV54170926; called by muse, mutect2, varscan2
- CAMK1G | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314268242, COSV50523270; called by muse, mutect2, varscan2
- CAMLG | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as rs1255711307, COSV51804357; called by muse, mutect2, varscan2
- CAND1 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs17854618, COSV73389692; called by muse, mutect2, varscan2
- CAPSL | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 45/102 reads (44%) | catalogued as COSV68438728, COSV68439408; called by muse, mutect2, varscan2
- CASKIN1 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58874368; called by muse, mutect2, varscan2
- CASP5 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52829894; called by muse, mutect2, varscan2
- CASP8AP2 | c.3586T>G p.L1196V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52748376; called by muse, mutect2, varscan2
- CASP8AP2 | c.5775T>G p.I1925M | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52748382; called by muse, mutect2, varscan2
- CATSPER2 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs1005796640, COSV58660263; called by muse, mutect2, varscan2
- CATSPERE | c.500G>T p.R167I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs1425909022, COSV63679679; called by muse, mutect2, varscan2
- CAVIN4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1304447896, COSV56866856; called by muse, mutect2, varscan2
- CBL | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50646215, COSV50656025; called by muse, mutect2, varscan2
- CBL | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV50635508; called by muse, mutect2, varscan2
- CBLL2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV60369355; called by muse, mutect2, varscan2
- CC2D1A | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58784683; called by muse, mutect2, varscan2
- CC2D2A | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs748642162, COSV67504387; called by muse, mutect2, varscan2
- CCAR1 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56271553; called by muse, mutect2, varscan2
- CCDC102B | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV60147455; called by muse, mutect2, varscan2
- CCDC110 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56872261; called by muse, mutect2, varscan2
- CCDC134 | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.061); catalogued as rs1413246072, COSV55388501; called by muse, mutect2, varscan2
- CCDC136 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52801912; called by muse, mutect2, varscan2
- CCDC136 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV52801920, COSV52805329; called by muse, mutect2, varscan2
- CCDC138 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.549); catalogued as rs937043859, COSV54569613; called by muse, mutect2
- CCDC14 | c.2164G>T p.E722* (on ENST00000488653; = p.E674* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV59946063; called by muse, mutect2, varscan2
- CCDC141 | c.3613G>T p.E1205* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV55377357, COSV99836606; called by muse, mutect2, varscan2
- CCDC158 | c.3160T>G p.S1054A | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV66356608; called by muse, mutect2, varscan2
- CCDC158 | c.1831-1G>T p.X611_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV66355442; called by muse, mutect2
- CCDC158 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | catalogued as COSV66355899; called by muse, mutect2, varscan2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, mutect2, varscan2
- CCDC180 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 13/154 reads (8%) | catalogued as rs1241841756, COSV100826638; called by muse, mutect2
- CCDC186 | c.2401C>A p.Q801K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV65161634; called by muse, mutect2, varscan2
- CCDC28A | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416056363, COSV60425425; called by muse, mutect2, varscan2
- CCDC32 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs139886034; called by muse, mutect2, varscan2
- CCDC6 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 45/133 reads (34%) | catalogued as rs746439006, COSV99569346; called by muse, mutect2, varscan2
- CCDC62 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53435438; called by muse, mutect2, varscan2
- CCDC73 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV58801159; called by muse, mutect2, varscan2
- CCDC73 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183881895, COSV100067314; called by muse, mutect2, varscan2
- CCDC8 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56772366; called by muse, mutect2, varscan2
- CCDC88A | c.3008A>G p.N1003S | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.208); catalogued as COSV55065347; called by muse, mutect2, varscan2
- CCDC88A | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55060025; called by muse, mutect2, varscan2
- CCDC96 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59508971; called by muse, mutect2, varscan2
- CCNA1 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.205); catalogued as COSV55222672, COSV99714179; called by muse, mutect2, varscan2
- CCNB1 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV56510525; called by muse, mutect2, varscan2
- CCSER1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV61446483; called by muse, mutect2
- CD163 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100775789, COSV100775979; called by muse, mutect2, varscan2
- CD180 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs376887530, COSV56518661; called by muse, mutect2, varscan2
- CD1E | c.893T>G p.I298S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100936971; called by muse, varscan2
- CD1E | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63771880; called by muse, mutect2, varscan2
- CD244 | c.842G>T p.R281I (on ENST00000368033 / NM_001166663.2; = p.R276I on NM_016382.4) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100458939, COSV59239525; called by muse, mutect2, varscan2
- CD276 | c.1585G>T p.D529Y (on ENST00000318443 / NM_001024736.2; = p.D311Y on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV59204543; called by muse, mutect2, varscan2
- CD300A | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV60409666; called by muse, varscan2
- CD300A | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV60410539; called by muse, mutect2, varscan2
- CD37 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV60544836; called by muse, mutect2, varscan2
- CD84 | c.606T>G p.N202K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV60869422; called by muse, mutect2, varscan2
- CD96 | c.1129C>A p.L377I (on ENST00000283285 / NM_198196.3; = p.L361I on NM_005816.5) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51919040, COSV51922856; called by muse, mutect2, varscan2
- CDC20B | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 45/146 reads (31%) | catalogued as COSV57054383; called by muse, mutect2, varscan2
- CDC23 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs767536014, COSV67510097; called by muse, mutect2, varscan2
- CDC23 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV67510185; called by muse, mutect2, varscan2
- CDC25A | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56770196; called by muse, mutect2, varscan2
- CDC42BPA | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62014946; called by muse, mutect2, varscan2
- CDC42BPB | c.4250C>T p.A1417V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as rs776462657, COSV63475910; called by muse, mutect2, varscan2
- CDC5L | c.1718A>C p.E573A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65176607; called by muse, mutect2, varscan2
- CDC6 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs757198932, COSV52930944; called by muse, mutect2, varscan2
- CDH10 | c.2093C>A p.P698H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.903); catalogued as COSV100050933; called by muse, mutect2, varscan2
- CDH2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769462371, COSV52272249, COSV52275539; called by muse, mutect2
- CDH8 | c.1276A>C p.R426= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100180787; called by muse, mutect2, varscan2
- CDH9 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as COSV50268721, COSV50334149; called by muse, mutect2, varscan2
- CDHR3 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs765982493, COSV58417555; called by muse, mutect2, varscan2
- CDK19 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349823433, COSV60449149; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3082A>C p.K1028Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV62576071; called by muse, varscan2
- CDK8 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV67421686; called by muse, mutect2, varscan2
- CELF2 | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.695); catalogued as COSV64927778; called by muse, mutect2, varscan2
- CENPC | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV56621909; called by muse, mutect2, varscan2
- CENPE | c.3846C>T p.I1282= | Splice Region (SNP) | VAF 17/58 reads (29%) | catalogued as COSV54384283; called by muse, mutect2, varscan2
- CENPF | c.3250G>T p.E1084* | Nonsense Mutation (SNP) | VAF 53/168 reads (32%) | catalogued as rs1558183041, COSV65276487; called by muse, mutect2, varscan2
- CENPF | c.6380G>A p.R2127H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs776162995, COSV65275853; called by muse, mutect2, varscan2
- CENPI | c.778-1G>T p.X260_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99515242; called by muse, mutect2
- CENPN | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528102999, COSV55141477; called by muse, mutect2, varscan2
- CEP104 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100986605; called by muse, mutect2, varscan2
- CEP152 | c.2960G>A p.R987Q | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755071182, COSV57858956; called by muse, mutect2, varscan2
- CEP152 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57861377; called by muse, mutect2, varscan2
- CEP162 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs773293017, COSV57620079; called by muse, mutect2, varscan2
- CEP192 | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV58067204; called by muse, mutect2, varscan2
- CEP192 | c.4786C>A p.L1596I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV58061140, COSV58062792; called by muse, mutect2
- CEP290 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs774824252, COSV100468397; called by muse, mutect2, varscan2
- CEP63 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV100132691; called by muse, mutect2
- CEP76 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV50867679; called by muse, mutect2, varscan2
- CEP89 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV59861983; called by muse, mutect2, varscan2
- CERS3 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52571190; called by muse, mutect2, varscan2
- CES1 | c.537-1G>A p.X179_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV62088400; called by muse, mutect2, varscan2
- CFAP251 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs947499425, COSV56607728, COSV99996338; called by muse, mutect2, varscan2
- CFAP251 | c.1921C>A p.L641I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs762945575, COSV56611694, COSV56612182; called by muse, mutect2, varscan2
- CFAP251 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776727712, COSV56608786; called by muse, mutect2, varscan2
- CFAP299 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866257430, COSV63880963; called by muse, mutect2, varscan2
- CFAP300 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs140641107; called by muse, mutect2
- CFAP44 | c.2611C>A p.R871S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV55613431, COSV55615803; called by muse, mutect2, varscan2
- CFAP47 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.476); catalogued as COSV52887985, COSV52891836; called by muse, mutect2, varscan2
- CFAP53 | c.1504C>A p.H502N | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68352365; called by muse, mutect2, varscan2
- CFAP54 | c.7064G>T p.G2355V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV100733078; called by muse, mutect2, varscan2
- CFAP61 | c.1463A>C p.K488T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV55637137; called by muse, mutect2, varscan2
- CFAP69 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV60186802; called by muse, mutect2, varscan2
- CFAP70 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as rs1306301088, COSV60283268; called by muse, mutect2, varscan2
- CFAP74 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs193075593; called by muse, mutect2, varscan2
- CFAP91 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs562410253, COSV56341898, COSV99847226; called by muse, mutect2, varscan2
- CFAP92 | c.1052A>T p.K351I | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54048090; called by muse, mutect2, varscan2
- CFAP92 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV99414687; called by muse, mutect2, varscan2
- CFDP1 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52210389, COSV52210582; called by muse, mutect2, varscan2
- CFH | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV62778164, COSV62778237; called by muse, mutect2, varscan2
- CFHR3 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.943); catalogued as COSV66402707; called by muse, mutect2, varscan2
- CGAS | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV64808529, COSV64809114; called by muse, mutect2, varscan2
- CGGBP1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV58852424; called by muse, mutect2, varscan2
- CHD1L | c.579C>T p.F193= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as COSV63613809; called by muse, mutect2, varscan2
- CHD5 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs774223603, COSV52419511, COSV52421012; called by muse, mutect2, varscan2
- CHD5 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1435656050, COSV52407518; called by muse, mutect2, varscan2
- CHD6 | c.8148G>T p.*2716Yext*12 | Nonstop Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV64692505; called by muse, mutect2, varscan2
- CHD7 | c.7469C>T p.S2490L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.629); catalogued as rs371595770, COSV71110807; called by muse, mutect2, varscan2
- CHD9 | c.895A>C p.N299H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV68299019; called by muse, mutect2, varscan2
- CHD9 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68299023; called by muse, mutect2, varscan2
- CHDH | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757045949, COSV55455112; called by muse, mutect2, varscan2
- CHEK1 | c.668A>C p.E223A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as COSV54024545; called by muse, mutect2, varscan2
- CHGA | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147517274; called by muse, mutect2, varscan2
- CHL1 | c.2113G>T p.E705* (on ENST00000397491 / NM_001253387.1; = p.E721* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV56597852; called by muse, mutect2, varscan2
- CHL1 | c.2541A>C p.I847= (on ENST00000397491 / NM_001253387.1; = p.I863= on NM_006614.4) | Splice Region (SNP) | VAF 15/79 reads (19%) | catalogued as COSV56597862; called by muse, mutect2, varscan2
- CHL1 | c.2891A>C p.E964A (on ENST00000397491 / NM_001253387.1; = p.E980A on NM_006614.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV56597870; called by muse, mutect2, varscan2
- CHMP2B | c.369A>C p.Q123H | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV55463023; called by muse, mutect2, varscan2
- CHN1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV69296967; called by muse, varscan2
- CHRD | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV52608684; called by muse, mutect2, varscan2
- CHRM2 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 14/146 reads (10%) | catalogued as COSV57769059; called by muse, mutect2
- CHRM2 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as COSV57777646; called by muse, mutect2, varscan2
- CHRNB3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.361); catalogued as rs760539559, COSV51496154; called by muse, mutect2, varscan2
- CHST15 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs375217023; called by muse, mutect2, varscan2
- CHUK | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV64918251; called by muse, mutect2, varscan2
- CHUK | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV64917507, COSV64918255; called by muse, mutect2, varscan2
- CKAP5 | c.3841C>A p.H1281N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV56364357, COSV56370466; called by muse, mutect2, varscan2
- CLCA4 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55369553; called by muse, mutect2, varscan2
- CLDN10 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV54823618; called by muse, mutect2, varscan2
- CLDN23 | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as rs1449607215, COSV101093087, COSV67731691; called by muse, mutect2
- CLEC10A | c.694C>A p.L232I (on ENST00000254868 / NM_182906.4; = p.L208I on NM_006344.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99644657; called by muse, mutect2, varscan2
- CLEC4F | c.1724G>A p.C575Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as COSV55480350; called by muse, mutect2, varscan2
- CLEC7A | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100021099; called by muse, mutect2, varscan2
- CLGN | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as COSV57773385, COSV57776268; called by muse, varscan2
- CLHC1 | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV68464460; called by muse, mutect2, varscan2
- CLIC2 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58937648; called by muse, mutect2, varscan2
- CLIC6 | c.1546G>A p.A516T (on ENST00000360731 / NM_001317009.2; = p.A498T on NM_053277.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs148002160; called by muse, mutect2, varscan2
- CLIC6 | c.2027C>T p.A676V (on ENST00000360731 / NM_001317009.2; = p.A658V on NM_053277.3) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs772153839, COSV62448356; called by muse, mutect2, varscan2
- CLIP4 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60750480; called by muse, mutect2, varscan2
- CLMN | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV54184743; called by muse, mutect2, varscan2
- CLNS1A | c.232T>G p.L78V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99628000; called by muse, mutect2, varscan2
- CLPX | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs771233943, COSV55643686; called by muse, mutect2, varscan2
- CLTC | c.2520C>A p.F840L | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as COSV52249552; called by muse, mutect2, varscan2
- CLU | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57067344; called by muse, mutect2, varscan2
- CLUAP1 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100489602, COSV58894697; called by mutect2, varscan2
- CLUH | c.1679G>A p.R560H (on ENST00000435359; = p.R598H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298969080, COSV101425707; called by muse, mutect2
- CLUL1 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as COSV58112663; called by muse, mutect2, varscan2
- CLVS1 | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV57978554; called by muse, mutect2, varscan2
- CLVS1 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV57979415; called by muse, mutect2, varscan2
- CMTM7 | c.331T>C p.S111P | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV58551412; called by muse, mutect2, varscan2
- CMYA5 | c.5655C>A p.F1885L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV71407414, COSV71409273; called by muse, mutect2, varscan2
- CMYA5 | c.7300C>T p.Q2434* | Nonsense Mutation (SNP) | VAF 47/155 reads (30%) | catalogued as COSV71407418; called by muse, mutect2, varscan2
- CMYA5 | c.12056G>A p.R4019K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV69745850; called by muse, mutect2, varscan2
- CNBD1 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs774426451, COSV73074095; called by muse, mutect2, varscan2
- CNGA2 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1392643398, COSV100323648, COSV61705312; called by muse, mutect2, varscan2
- CNGB1 | c.585G>A p.A195= | Splice Region (SNP) | VAF 14/46 reads (30%) | catalogued as rs530319460, COSV99202304; ClinVar: uncertain significance; called by muse, mutect2
- CNOT1 | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55316550; called by muse, mutect2, varscan2
- CNOT1 | c.4918C>T p.R1640* | Nonsense Mutation (SNP) | VAF 31/101 reads (31%) | catalogued as COSV55314883; called by muse, mutect2, varscan2
- CNOT6L | c.487G>A p.A163T (on ENST00000504123 / NM_001286790.2; = p.A158T on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs766371188, COSV53701501; called by muse, mutect2, varscan2
- CNR1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV62986822; called by muse, mutect2, varscan2
- CNTN1 | c.825G>A p.W275* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs1332718825, COSV61642184; called by muse, mutect2, varscan2
- CNTN1 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV61642189; called by muse, mutect2, varscan2
- CNTN1 | c.2905G>T p.D969Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1555201472, COSV61642205; called by muse, mutect2, varscan2
- CNTN6 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV63177603, COSV63179589; called by muse, mutect2, varscan2
- CNTN6 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs774492055, COSV63172416; called by muse, mutect2, varscan2
- CNTN6 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610480, COSV63181378; called by muse, mutect2, varscan2
- CNTNAP2 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100668233, COSV62215270; called by muse, mutect2, varscan2
- CNTNAP2 | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100664934; called by muse, mutect2, varscan2
- CNTNAP4 | c.980G>T p.R327I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV56690055; called by muse, mutect2, varscan2
- CNTNAP4 | c.3247A>C p.N1083H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as COSV56690078; called by muse, mutect2, varscan2
- COBL | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs141474418, COSV54350876; called by muse, mutect2, varscan2
- COG6 | c.1587C>T p.I529= | Splice Region (SNP) | VAF 12/47 reads (26%) | catalogued as rs756253977, COSV62995439, COSV62997072; called by muse, mutect2, varscan2
- COL11A1 | c.4998G>T p.E1666D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV62189162; called by muse, mutect2, varscan2
- COL11A1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs372387693; called by muse, mutect2, varscan2
- COL11A2 | c.2272G>A p.E758K (on ENST00000341947 / NM_080680.3; = p.E651K on NM_080679.2) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1304713056, COSV59499234; called by muse, mutect2, varscan2
- COL12A1 | c.7596G>T p.K2532N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1430689789, COSV59389949; called by muse, mutect2, varscan2
- COL12A1 | c.4285G>T p.E1429* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV59400559; called by muse, mutect2, varscan2
- COL14A1 | c.1519A>C p.N507H | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV52860566; called by muse, mutect2, varscan2
- COL15A1 | c.3525dup p.L1176Ifs*39 | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | catalogued as rs773041610; called by mutect2, pindel, varscan2
- COL19A1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59574982; called by muse, mutect2, varscan2
- COL1A1 | c.3589G>A p.D1197N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV56804567; called by muse, mutect2, varscan2
- COL20A1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as rs779300811, COSV58921492; called by muse, mutect2, varscan2
- COL20A1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs569710367, COSV58921504; called by mutect2, varscan2
- COL24A1 | c.4748G>A p.G1583D | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273600226, COSV65309340; called by muse, mutect2, varscan2
- COL24A1 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65306550, COSV65309344; called by muse, mutect2, varscan2
- COL27A1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as rs771010276, COSV61924213; called by muse, mutect2, varscan2
- COL3A1 | c.469T>G p.S157A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100483885, COSV58592768; called by muse, mutect2, varscan2
- COL5A2 | c.4040A>C p.K1347T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66411537; called by muse, mutect2, varscan2
- COL6A5 | c.6652G>T p.E2218* (on ENST00000312481; = p.E2214* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as COSV99592687; called by muse, mutect2, varscan2
- COL6A6 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV62030252; called by muse, mutect2, varscan2
- COL9A2 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.874); catalogued as rs779917331, COSV101028443; called by muse, mutect2, varscan2
- COLQ | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV67525314; called by muse, mutect2, varscan2
- COPA | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292511645, COSV54100533; called by muse, mutect2, varscan2
- COPB1 | c.2446T>C p.C816R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99999451; called by muse, mutect2
- COPB1 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs754536521, COSV51447551; called by muse, mutect2, varscan2
- CPA1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782561684, CM139187, COSV50568458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.1692G>T p.E564D (on ENST00000651564; = p.E517D on NM_015692.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV99359212; called by muse, mutect2, varscan2
- CPB2 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51672226; called by muse, mutect2
- CPEB1 | c.1603C>T p.R535C (on ENST00000617958; = p.R470C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55618771, COSV55620131; called by muse, mutect2, varscan2
- CPEB1 | c.280C>T p.R94* (on ENST00000617958; = p.R34* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV71604286; called by muse, varscan2
- CPSF2 | c.137A>C p.D46A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.407); catalogued as COSV54099227; called by muse, mutect2, varscan2
- CRABP1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs771972939, COSV55116043; called by muse, mutect2, varscan2
- CRACR2B | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV58990325; called by muse, mutect2, varscan2
- CRB1 | c.3374T>C p.F1125S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100957792; called by muse, mutect2, varscan2
- CREBBP | c.3505C>T p.R1169C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52115098; called by muse, mutect2, varscan2
- CREM | c.921G>T p.K307N (on ENST00000429130; = p.K262N on NM_181571.3) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59768589; called by muse, mutect2, varscan2
- CRHBP | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV57189239; called by muse, mutect2, varscan2
- CRLF3 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as COSV60836296; called by muse, mutect2, varscan2
- CRNKL1 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs760353268, COSV66106268; called by muse, mutect2, varscan2
- CRYBG1 | c.5153G>A p.R1718Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs922185051, COSV64810956; called by muse, mutect2, varscan2
- CRYM | c.924T>G p.D308E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54832098; called by muse, mutect2, varscan2
- CSDE1 | c.1570G>A p.A524T (on ENST00000358528 / NM_001007553.3; = p.A493T on NM_007158.6) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV54752848; called by muse, mutect2, varscan2
- CSE1L | c.1976T>G p.F659C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53703203; called by muse, mutect2, varscan2
- CSHL1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs368141351, COSV51989027; called by muse, mutect2, varscan2
- CSMD2 | c.8639C>T p.S2880L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.027); catalogued as rs770765269, COSV53936605; called by mutect2, varscan2
- CSMD2 | c.8389C>T p.R2797W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs746116665, COSV53890915; called by muse, mutect2, varscan2
- CSMD3 | c.5512G>T p.E1838* (on ENST00000297405 / NM_001363185.1; = p.E1734* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV52126511, COSV52239165, COSV52313526; called by muse, mutect2, varscan2
- CSRP1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1316394144, COSV60637531; called by muse, mutect2, varscan2
- CSTL1 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.375); catalogued as COSV55678536; called by muse, mutect2
- CTDSPL2 | c.220A>C p.I74L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV99526761; called by muse, mutect2
- CTNNA1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1274345685, COSV57070748, COSV57077454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNB1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV62707932; called by muse, mutect2, varscan2
- CTPS1 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV65453239; called by muse, mutect2, varscan2
- CTTNBP2 | c.3608C>A p.S1203Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV50420189; called by muse, mutect2, varscan2
- CUL4A | c.2026G>A p.E676K (on ENST00000375440 / NM_001008895.4; = p.E576K on NM_003589.3) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58374207; called by muse, mutect2, varscan2
- CUL9 | c.4829C>T p.S1610L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs376817499; called by muse, mutect2, varscan2
- CWC22 | c.2555C>A p.S852* | Nonsense Mutation (SNP) | VAF 80/269 reads (30%) | catalogued as COSV99844083, COSV99844335; called by muse, mutect2, varscan2
- CXCR1 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV99826297; called by muse, mutect2
- CXCR2 | c.575T>G p.V192G | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100578911; called by muse, mutect2, varscan2
- CYFIP1 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs763053554; called by mutect2, varscan2
- CYFIP2 | c.866G>T p.R289I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59031190; called by muse, mutect2, varscan2
- CYP2E1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV53314227; called by muse, mutect2, varscan2
- CYP2E1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs199954662, COSV53312504, COSV53313458; called by muse, mutect2, varscan2
- CYP3A43 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55936932; called by muse, mutect2, varscan2
- CYP4F12 | c.365A>C p.N122T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61175029; called by muse, mutect2, varscan2
- CYP7A1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56963098, COSV56964475; called by muse, mutect2, varscan2
- CYP7B1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV59592415; called by muse, mutect2, varscan2
- CYSLTR1 | c.264T>G p.I88M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.357); catalogued as COSV64820649; called by muse, mutect2, varscan2
- DAB2 | c.147A>C p.K49N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV57916367; called by muse, mutect2, varscan2
- DACH1 | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57508863; called by muse, mutect2, varscan2
- DAP3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs772121458, COSV100546436; called by muse, mutect2, varscan2
- DAPK1 | c.3253C>A p.L1085I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63789222; called by muse, mutect2, varscan2
- DBF4B | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs774436262, COSV59258932, COSV59261867; called by mutect2, varscan2
- DCAF4L2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV60478406; called by muse, mutect2, varscan2
- DCDC1 | c.592C>T p.L198= | Splice Region (SNP) | VAF 20/49 reads (41%) | catalogued as COSV60849314; called by muse, mutect2, varscan2
- DCHS1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.608); catalogued as COSV55038658; called by muse, mutect2, varscan2
- DCHS1 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs962936794, COSV55038672; called by muse, mutect2, varscan2
- DDX11 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1221152082, COSV52500765; called by muse, mutect2
- DDX17 | c.738C>T p.I246= | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as rs201507084, COSV99318687; called by muse, mutect2, varscan2
- DDX19B | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV55364728; called by muse, mutect2, varscan2
- DDX23 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV56397324; called by muse, mutect2, varscan2
- DDX25 | c.344T>G p.M115R | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs561704, COSV54991464; called by muse, mutect2, varscan2
- DDX4 | c.1972A>C p.K658Q | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100737473; called by muse, mutect2, varscan2
- DDX43 | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64813237; called by muse, mutect2, varscan2
- DDX49 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs753913915, COSV53231250; called by muse, mutect2, varscan2
- DDX50 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.932); catalogued as COSV65292811; called by muse, mutect2, varscan2
- DDX50 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs752621338, COSV65292818; called by muse, mutect2, varscan2
- DDX58 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.09); catalogued as COSV100007980; called by muse, mutect2, varscan2
- DEFB106B | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs1335501799, COSV100128910; called by muse, mutect2, varscan2
- DEFB118 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV53620849; called by muse, mutect2, varscan2
- DEFB126 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs376573096; called by mutect2, varscan2
- DENND1C | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs536993980, COSV57569066; called by muse, mutect2, varscan2
- DENND4B | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100768367, COSV63410395; called by muse, mutect2, varscan2
- DENND4C | c.2971G>T p.E991* (on ENST00000434457 / NM_001330640.2; = p.E942* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as COSV66819687; called by muse, mutect2, varscan2
- DENND5A | c.1764A>C p.K588N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60235829; called by muse, mutect2, varscan2
- DEPDC4 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV54553948; called by muse, mutect2, varscan2
- DGKA | c.2199C>A p.F733L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59387171; called by muse, mutect2, varscan2
- DGKD | c.757G>A p.D253N (on ENST00000264057 / NM_152879.3; = p.D209N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1423888622, COSV51044404; called by muse, mutect2, varscan2
- DGKI | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV55949022; called by muse, mutect2, varscan2
- DGLUCY | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56367848; called by muse, mutect2, varscan2
- DHCR7 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs773048017, COSV62794796, COSV62796954; called by muse, mutect2, varscan2
- DHH | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV57202406; called by muse, mutect2, varscan2
- DHRS7 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV53666847; called by muse, mutect2, varscan2
- DHX8 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1181983132, COSV52254213; called by muse, mutect2, varscan2
- DHX9 | c.19T>G p.F7V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV62358482, COSV62359477; called by muse, mutect2, varscan2
- DIDO1 | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56627652; called by muse, mutect2, varscan2
- DIP2B | c.4445C>T p.S1482L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772210044, COSV56579943; called by mutect2, varscan2
- DISP2 | c.3215C>T p.A1072V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs770438703, COSV51128766; called by muse, mutect2, varscan2
- DKK1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV64760035; called by muse, mutect2, varscan2
- DLAT | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs782632175, COSV54771819; called by muse, mutect2, varscan2
- DLG2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54655572, COSV54663556; called by muse, mutect2, varscan2
- DLG2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs150043290, COSV65834644; called by muse, varscan2
- DLG4 | c.294G>T p.K98N (on ENST00000399506 / NM_001321075.3; = p.K141N on NM_001365.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV57240108; called by muse, mutect2, varscan2
- DLGAP1 | c.2490A>C p.K830N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59817972; called by muse, mutect2, varscan2
- DLGAP3 | c.2553C>A p.F851L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52395583; called by muse, mutect2, varscan2
- DMBT1 | c.7514G>A p.R2505Q (on ENST00000338354 / NM_001377530.1; = p.R1748Q on NM_004406.3) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.154); catalogued as rs537234062, COSV57532912; called by muse, mutect2, varscan2
- DMGDH | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as rs143021634, COSV54865650; called by muse, mutect2, varscan2
- DMP1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs781781034, COSV56820876; called by muse, mutect2, varscan2
- DMXL2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV51850352; called by muse, mutect2, varscan2
- DNAAF4 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV58249971, COSV58251528; called by muse, mutect2, varscan2
- DNAH1 | c.1965G>T p.K655N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs752337800, COSV70228755, COSV70238310; called by muse, mutect2, varscan2
- DNAH1 | c.6181G>A p.A2061T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs775541195, COSV70231927; called by muse, mutect2, varscan2
- DNAH1 | c.9699C>A p.F3233L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV70227406; called by muse, mutect2, varscan2
- DNAH10 | c.789G>T p.M263I (on ENST00000409039; = p.M202I on NM_207437.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV68996737; called by muse, mutect2, varscan2
- DNAH11 | c.3281T>C p.V1094A | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100178557; called by muse, varscan2
- DNAH11 | c.3295T>G p.F1099V | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1408438549, COSV100180080, COSV60965995; called by muse, varscan2
- DNAH11 | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1166407911, COSV100178473, COSV60966002; called by muse, mutect2, varscan2
- DNAH11 | c.7119_7120insC p.S2374Qfs*2 | Frame Shift Ins (INS) | VAF 12/95 reads (13%) | catalogued as COSV100178561; called by mutect2, pindel, varscan2
- DNAH11 | c.11521C>T p.R3841* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as rs988794959, COSV60966014; called by muse, mutect2
- DNAH17 | c.8605C>A p.L2869M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV67758013; called by muse, mutect2
- DNAH17 | c.8148C>A p.F2716L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.091); catalogued as rs374165283; called by muse, mutect2, varscan2
- DNAH2 | c.2798A>G p.D933G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV101209165; called by muse, mutect2, varscan2
- DNAH2 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs569552800, COSV66722253; called by muse, mutect2, varscan2
- DNAH2 | c.3429G>T p.E1143D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV101209167; called by muse, mutect2, varscan2
- DNAH2 | c.7868T>C p.F2623S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101209168; called by muse, varscan2
- DNAH3 | c.8179G>T p.E2727* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV54534050; called by muse, mutect2, varscan2
- DNAH3 | c.4309G>T p.E1437* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV54534090; called by muse, mutect2, varscan2
- DNAH5 | c.7778G>A p.G2593E | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54236569; called by muse, mutect2, varscan2
- DNAH5 | c.3312G>T p.K1104N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54237825; called by muse, mutect2, varscan2
- DNAH7 | c.10081T>G p.L3361V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV56773830; called by muse, mutect2, varscan2
- DNAH7 | c.6708T>G p.I2236M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56760766; called by muse, mutect2, varscan2
- DNAH8 | c.4752C>A p.F1584L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100543567, COSV59434706; called by muse, varscan2
- DNAH9 | c.2640G>A p.W880* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV52360093; called by muse, mutect2, varscan2
- DNAH9 | c.9530C>T p.S3177L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99305217; called by muse, mutect2, varscan2
- DNAI1 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV54278927, COSV54280092; called by muse, mutect2, varscan2
- DNAI4 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100925267, COSV64020714; called by muse, mutect2, varscan2
- DNAJC13 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1232607951, COSV53447059; called by muse, mutect2
- DNAJC28 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV58721187; called by muse, mutect2, varscan2
- DNAJC6 | c.174-1G>T p.X58_splice | Splice Site (SNP) | VAF 12/164 reads (7%) | catalogued as COSV99674504; called by muse, mutect2
- DNASE1L3 | c.231-1G>T p.X77_splice | Splice Site (SNP) | VAF 31/79 reads (39%) | catalogued as COSV59156634; called by muse, mutect2, varscan2
- DNM1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100359767; called by muse, mutect2, varscan2
- DNM3 | c.1735C>T p.R579W (on ENST00000355305 / NM_001350206.2; = p.R569W on NM_015569.5) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253104482, COSV62456982; called by muse, varscan2
- DNTT | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV64523306; called by muse, mutect2, varscan2
- DOCK2 | c.5486A>G p.D1829G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99911464; called by muse, mutect2, varscan2
- DPF1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs1257922405, COSV62792645; called by muse, mutect2, varscan2
- DPH6 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV56616505, COSV56619258; called by muse, mutect2, varscan2
- DPP4 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | catalogued as COSV62108060; called by muse, mutect2
- DPP6 | c.550dup p.I184Nfs*2 (on ENST00000377770 / NM_001364500.2; = p.I122Nfs*2 on NM_001936.5) | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | catalogued as rs773847741; called by mutect2, varscan2
- DPP8 | c.826G>T p.E276* (on ENST00000341861 / NM_001320875.2; = p.E260* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55676443; called by muse, mutect2, varscan2
- DPPA4 | c.878+2T>C p.X293_splice | Splice Site (SNP) | VAF 33/87 reads (38%) | catalogued as COSV59511530; called by muse, mutect2, varscan2
- DPY30 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV54459248; called by muse, mutect2
- DPYD | c.2522A>T p.K841I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV64605766; called by muse, mutect2, varscan2
- DPYD | c.1893C>A p.D631E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV64605774, COSV64615868; called by muse, mutect2, varscan2
- DPYD | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV64605783; called by muse, mutect2, varscan2
- DPYD | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV60080845, COSV60082915; called by muse, mutect2, varscan2
- DRAM2 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs917466805, COSV54415921; called by muse, mutect2, varscan2
- DRG1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs369620921, COSV100513695; called by muse, mutect2, varscan2
- DRP2 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV65809399, COSV65809898; called by muse, mutect2, varscan2
- DSCAM | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs201979167; called by muse, mutect2, varscan2
- DSE | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV59065534; called by muse, mutect2, varscan2
- DSG1 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV57137176; called by muse, mutect2, varscan2
- DSG2 | c.1290A>C p.K430N | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99853016; called by muse, mutect2
- DSP | c.7078G>A p.E2360K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.603); catalogued as COSV65793923; called by muse, mutect2, varscan2
- DSPP | c.2963G>A p.S988N | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); catalogued as COSV99217046; called by muse, mutect2, varscan2
- DST | c.15562G>A p.A5188T (on ENST00000361203 / NM_001374722.1; = p.A2776T on NM_015548.5) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.436); catalogued as rs553940584, COSV55025497, COSV99759291; called by muse, varscan2
- DST | c.15542G>A p.R5181Q (on ENST00000361203 / NM_001374722.1; = p.R2769Q on NM_015548.5) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201501487, COSV55002147; called by muse, varscan2
- DST | c.14973G>T p.E4991D (on ENST00000361203 / NM_001374722.1; = p.E2579D on NM_015548.5) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as COSV55025518; called by muse, mutect2, varscan2
- DST | c.4896G>T p.E1632D | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs753295452, COSV54997759, COSV99754072; called by muse, mutect2, varscan2
- DST | c.1969G>T p.E657* (on ENST00000361203 / NM_001374722.1; = p.E331* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV55025534; called by muse, mutect2, varscan2
- DUOX2 | c.3537C>A p.F1179L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs1566972018, COSV66533091; called by muse, mutect2, varscan2
- DUOX2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs777734937, COSV66533097; called by muse, mutect2, varscan2
- DUXA | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV73729785, COSV73729847; called by muse, mutect2, varscan2
- DYDC2 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV55472795; called by muse, mutect2, varscan2
- DYNAP | c.625C>A p.H209N (on ENST00000321600; = p.H183N on NM_173629.3) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100391726, COSV58665983; called by muse, mutect2, varscan2
- DYNC2I1 | c.2121G>T p.L707F | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs766537162, COSV68105832; called by muse, mutect2, varscan2
- DYRK1B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV55683302; called by muse, mutect2, varscan2
- DYRK3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454132363, COSV65605835; called by muse, mutect2, varscan2
- DYSF | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV50281990; called by muse, mutect2, varscan2
- DZIP1L | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV59522212; called by muse, mutect2, varscan2
- E2F3 | c.5G>T p.R2I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.396); catalogued as COSV60898532; called by muse, mutect2, varscan2
- E2F8 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 57/151 reads (38%) | catalogued as COSV51464772; called by muse, mutect2, varscan2
- EBF1 | c.1623C>A p.F541L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.15); catalogued as COSV100565592; called by muse, mutect2, varscan2
- ECM2 | c.1307-1G>T p.X436_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV60741840; called by muse, mutect2, varscan2
- ECT2 | c.2403G>A p.E801= (on ENST00000392692 / NM_001349098.2; = p.E770= on NM_018098.6 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 79/317 reads (25%) | catalogued as rs1183539692, COSV104372255, COSV51691069; called by muse, mutect2, varscan2
- ECT2L | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62885757; called by muse, mutect2, varscan2
- ECT2L | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV62885760; called by muse, mutect2, varscan2
- EDIL3 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1477118490, COSV99675745; called by muse, mutect2, varscan2
- EDN1 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV65080559; called by muse, mutect2, varscan2
- EEA1 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as COSV59287694; called by muse, mutect2, varscan2
- EEF1A2 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV53207055; called by muse, mutect2, varscan2
- EFCAB5 | c.1208T>G p.F403C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1167935954, COSV57932929; called by muse, mutect2, varscan2
- EFCAB5 | c.4088C>A p.S1363Y | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV57932947; called by muse, mutect2, varscan2
- EFCAB6 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as rs772599532, COSV53060948; called by muse, mutect2, varscan2
- EFHB | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as rs746037198, COSV55550282; called by muse, mutect2, varscan2
- EFHB | c.301A>C p.K101Q | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); catalogued as COSV55550330; called by muse, mutect2, varscan2
- EFR3A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1291653738, COSV54459529; called by muse, mutect2, varscan2
- EFR3A | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99602762; called by muse, mutect2, varscan2
- EFTUD2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53656007; called by muse, mutect2, varscan2
- EGFLAM | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59307610; called by muse, mutect2
- EGR4 | c.1222G>A p.A408T (on ENST00000545030; = p.A305T on NM_001965.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV71532172; called by muse, mutect2, varscan2
- EHBP1 | c.2435C>A p.S812Y | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs368672515; called by muse, mutect2, varscan2
- EHD3 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as COSV59031846; called by muse, mutect2, varscan2
- EIF2S1 | c.253T>G p.L85V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56452814; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs1227597607, COSV57516886; called by muse, mutect2, varscan2
- EIF5A2 | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55542948; called by muse, mutect2, varscan2
- EIF5B | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as COSV56814664; called by muse, mutect2, varscan2
- EIPR1 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100160361; called by muse, mutect2, varscan2
- ELAC1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs1056516547, COSV53996906; called by muse, mutect2, varscan2
- ELAVL4 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV63917508; called by muse, mutect2, varscan2
- ELF1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs12876618, COSV99522961; called by muse, mutect2, varscan2
- ELL2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 49/179 reads (27%) | catalogued as rs1416098476, COSV52981190; called by muse, mutect2, varscan2
- ELP1 | c.3424C>T p.R1142* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as rs768015419, COSV65898615; called by muse, mutect2, varscan2
- EMB | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV57483180; called by muse, varscan2
- EMILIN2 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54422529, COSV54425336; called by muse, mutect2, varscan2
- EML5 | c.3985G>T p.E1329* | Nonsense Mutation (SNP) | VAF 65/219 reads (30%) | catalogued as COSV100715138, COSV61348305; called by muse, mutect2, varscan2
- EML5 | c.301T>G p.L101V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61348316; called by muse, mutect2, varscan2
2,708 further variants in this file (1,992 protein-altering or splice-affecting, 620 silent, 96 other) are not listed here.
